Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H1, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H1-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Left adrenal, adrenalectomy: Pheochromocytoma. See note.

NOTE: Immunohistochemistry studies will be performed and reported as a supplemental report.

CLINICAL INFORMATION: Allocate Order to Protocol:
Clinical History:

Brief

pheochromocytoma Specimen Taken For Protocol:
Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:
pheochromocytoma Operative Findings: left bilobular adrenal
tumor

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT, Pheochromocytoma

GROSS DESCRIPTION: One specimen is received fresh in a container labeled with the patient's name and medical record number, and "left pheochromocytoma". It consists of a red-tan irregular-shaped soft tissue mass measuring 11 x 5 x 2 cm. It weighs 74.65 grams. Multiple nodules are palpated. The specimen is inked in black and opened to reveal 3 nodules measuring as follows: #1 [5 x 3 x 2], #2 [0.8 x 0.7 x 0.5 cm], and #3 [1.7 x 1.8 x 1 cm]. The cut surface of each is red-tan, variegated, and hemorrhagic. The larger nodule appears partially necrotic. Approximately 50% of each nodule is procured for

Procurement was performed by _____ on _____ at _____

A rim of normal-appearing adrenal parenchyma can be grossly noted. Representative sections are submitted as follows: A, B, C - section of one nodule; D, E, F - second nodule; G - section of the smaller nodule.

Gross description dictated by _____

No consultants

#

#

Requested By: _____

Do not file in Medical Record

ICD O-3

Pheochromocytoma NOS
8706/0

Site @ Adrenal gland NOS
C74.9

JW 8/29/13

[page 2 of 3]
~~Supplemental Report~~CASE NUMBER:
SUPPLEMENTAL

SUPPLEMENTAL REPORT

REASON FOR THE SUPPLEMENTAL REPORT: To report the result of Immunohistochemistry studies: The tumor stains strongly and diffusely for chromogranin, synaptophysin and CD56. Inhibin stain is negative. S100 highlights the sustentacular cells in the medulla. The diagnosis remains unchanged.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

DIAGNOSIS: Left adrenal, adrenalectomy: Pheochromocytoma.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief

Clinical History:

pheochromocytoma Specimen Taken For Protocol:

Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative

Diagnosis:

pheochromocytoma Operative Findings: left bilobular adrenal tumor

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT, Pheochromocytoma

GROSS DESCRIPTION: One specimen is received fresh in a container labeled with the patient's name and medical record number, and "left pheochromocytoma". It consists of a red-tan irregular-shaped soft tissue mass measuring 11 x 5 x 2 cm. It weighs 74.65 grams. Multiple nodules are palpated. The specimen is inked in black and opened to reveal 3 nodules measuring as follows: #1 [5 x 3 x 2], #2 [0.8 x 0.7 x 0.5 cm], and #3 [1.7 x 1.8 x 1 cm]. The cut surface of each is red-tan, variegated, and hemorrhagic. The larger nodule appears partially necrotic. Approximately 50% of each nodule is procured for

Procurement was performed by _____ on _____ at _____ a.m. A rim of normal-appearing adrenal parenchyma can be grossly noted.

Representative sections are submitted as follows: A, B, C - section of one nodule; D, E, F - second nodule; G - section of the smaller nodule.

Requested By:

Do not file in Medical Record

[page 3 of 3]
Gross description dictated by

No consultants

#

#

Requested By:

Do not file in Medical Record

Criteria	lw 5/23/13	Yes	No
Prior Malignancy History	Radical prostatectomy	☒	☒

Source: NCI Genomic Data Commons file 5f9d6ed7-b240-4433-9f9c-197d5658ac16 (TCGA-QR-A6H1.6B939F96-F2EE-4B41-9FFC-E017F3129A12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).